Somatic mutation profile of tumor specimen TCGA-HT-8013-01A (aliquot TCGA-HT-8013-01A-11D-2395-08) from TCGA case TCGA-HT-8013, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.7 years (13,753 days).
Specimen TCGA-HT-8013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aceec952-c9a4-42c4-b93f-e793e274a24b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8013-10A (Blood Derived Normal), aliquot TCGA-HT-8013-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34dec98-890c-4979-bb36-446ffb39cdb5

The open-access MAF lists 27 somatic variants for this specimen: 25 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 23, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 120/301 reads (40%) | catalogued as COSV64871669, COSV64882646; called by muse, mutect2, varscan2
- DBNDD2 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61919353; called by muse, varscan2
- ERN2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373315072; called by muse, mutect2, varscan2
- ESYT3 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs369262503; called by muse, mutect2, varscan2
- HTR3A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs918546404, COSV55471345, COSV55471669; called by muse, mutect2
- IL9R | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54901951; called by muse, mutect2, varscan2
- ITIH6 | c.1958T>C p.V653A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54494083; called by muse, mutect2
- KANK4 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs374086260; called by muse, mutect2, varscan2
- KIAA0753 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV63818860; called by muse, mutect2
- MAMLD1 | c.284T>A p.M95K | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV53380281; called by muse, mutect2, varscan2
- MON2 | c.5108A>G p.D1703G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54814216; called by muse, mutect2, varscan2
- PCNX3 | c.4123G>T p.V1375F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV63140507; called by muse, mutect2
- PGK1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59372272; called by muse, mutect2, varscan2
- POLQ | c.7340G>A p.R2447H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760099812, COSV51758078; called by muse, mutect2, varscan2
- RBM12B | c.2960A>G p.N987S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV67898823; called by muse, mutect2, varscan2
- RYR2 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374397612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as rs1406096182, COSV59286898; called by muse, mutect2, varscan2
- STK32C | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.065); catalogued as rs1277523547, COSV53845609; called by muse, mutect2
- TTN | c.62911G>A p.D20971N (on ENST00000591111; = p.D13547N on NM_003319.4) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | PolyPhen probably damaging (0.998); catalogued as rs757888367, COSV60313118; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZNF215 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs753963457, COSV53494734; called by muse, mutect2, varscan2
- ZNF438 | c.1948G>C p.G650R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59200388; called by muse, mutect2, varscan2
- CNTNAP2 | c.1091del p.L364* | Frame Shift Del (DEL) | VAF 57/122 reads (47%) | called by mutect2, pindel, varscan2
- OR1A2 | c.48A>G p.G16= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV67936761; called by muse, mutect2, varscan2
- SMIM19 | c.30C>T p.D10= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs774101022, COSV60606488; called by muse, mutect2, varscan2
